Somatic mutation profile of tumor specimen TARGET-10-PASFLK-09A (aliquot TARGET-10-PASFLK-09A-01D) from TARGET case TARGET-10-PASFLK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,390 days).
Specimen TARGET-10-PASFLK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93a774c3-6999-4245-aa88-35c0dbc23f82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASFLK-10A (Blood Derived Normal), aliquot TARGET-10-PASFLK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac5574ca-54f8-42c6-b906-33f6d06efc84

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 3, Intron 3, 3'UTR 2, Splice Site 1, In Frame Del 1, 5'Flank 1, 5'UTR 1, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 65/133 reads (49%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHEB | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554438588, COSV51264604; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55896457, COSV99226273; called by muse, mutect2
- ATP8B3 | c.2741T>C p.V914A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs370081945; called by muse, mutect2, varscan2
- BCORL1 | c.1596del p.G533Vfs*115 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as COSV54399024; called by mutect2, pindel, varscan2
- BCORL1 | c.5035dup p.S1679Ffs*7 | Frame Shift Ins (INS) | VAF 23/39 reads (59%) | catalogued as rs1248905110; called by mutect2, pindel, varscan2
- CACHD1 | c.2549A>G p.H850R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51560276; called by muse, mutect2, varscan2
- CDH8 | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901992; called by muse, mutect2, varscan2
- CTBS | c.392A>T p.K131I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV55364853; called by muse, mutect2, varscan2
- EIF4E1B | c.61_63del p.K21del | In Frame Del (DEL) | VAF 6/61 reads (10%) | catalogued as rs762488024; called by mutect2, pindel, varscan2
- FERD3L | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51764402; called by muse, mutect2, varscan2
- FREM3 | c.2969A>G p.D990G | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV61682668; called by muse, mutect2, varscan2
- HTR4 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV58805213; called by muse, mutect2, varscan2
- INTS5 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV57953729; called by muse, mutect2, varscan2
- LONP1 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs377388291; called by muse, mutect2, varscan2
- LRP1 | c.576C>T p.N192= | Splice Region (SNP) | VAF 27/83 reads (33%) | catalogued as rs748684528, COSV54522963; called by muse, mutect2, varscan2
- NMRAL1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV52060413, COSV52061226; called by muse, mutect2, varscan2
- NRXN3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1478153407, COSV99819350; called by muse, mutect2, varscan2
- OR9Q1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202075369, COSV59037940; called by muse, mutect2, varscan2
- PLA2G2E | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs761286861, COSV64290961; called by muse, mutect2, varscan2
- PRLHR | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1341862555, COSV53305222; called by muse, mutect2, varscan2
- RYR3 | c.4492G>A p.V1498M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs375515948; called by muse, mutect2, varscan2
- SP140L | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV54748660; called by mutect2, varscan2
- SRGAP1 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV61903839; called by muse, mutect2
- ZNF536 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV62834571; called by muse, mutect2
- NOX4 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC22B4P | n.537-1G>A | Splice Site (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- TCF4 | c.1490T>C p.M497T | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- TTN | c.9473T>G p.V3158G (on ENST00000591111; = p.V3112G on NM_003319.4) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | PolyPhen possibly damaging (0.536); called by muse, mutect2
- ARHGAP28 | c.1911C>T p.D637= (on ENST00000383472 / NM_001366230.1; = p.D478= on NM_001010000.3) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs377109412; called by muse, mutect2, varscan2
- ARHGEF5 | c.2547C>T p.T849= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs747829419, COSV99282528; called by mutect2, varscan2
- COMP | c.1782C>T p.D594= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as rs751974065; called by muse, mutect2, varscan2
- KRT15 | c.612C>T p.G204= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs577866815, COSV54180244; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621061 C>T | 3'Flank (SNP) | VAF 10/25 reads (40%) | catalogued as rs779891187, COSV54090934; called by muse, mutect2, varscan2
- CCDC85C | c.*11241C>T | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- CYTH2 | c.19+15G>A | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs1484432599, COSV100287320; called by muse, mutect2, varscan2
- DPP6 | c.2451+100C>T | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs919469634, COSV59605107; called by muse, mutect2
- HNRNPLP2 | n.300G>A | RNA (SNP) | VAF 8/43 reads (19%) | catalogued as rs916194284; called by muse, mutect2, varscan2
- LRRC52 | c.*55G>T | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- MAGI2 | c.538+68C>T | Intron (SNP) | VAF 7/100 reads (7%) | catalogued as rs1365366572; called by muse, mutect2
- NCALD | c.-6G>A | 5'UTR (SNP) | VAF 38/72 reads (53%) | catalogued as rs570098457, COSV99637604; called by muse, mutect2, varscan2
- SCRN1 | chr7:29990141 C>T | 5'Flank (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
